Somatic mutation profile of tumor specimen TCGA-E1-A7Z2-01A (aliquot TCGA-E1-A7Z2-01A-21D-A34J-08) from TCGA case TCGA-E1-A7Z2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 58.4 years (21,341 days).
Specimen TCGA-E1-A7Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b46df1b9-117e-4dea-9454-7884c3fad7cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7Z2-10A (Blood Derived Normal), aliquot TCGA-E1-A7Z2-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d434f50-f716-44e1-bad1-aa7c70739205

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Frame Shift Del 3, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 46/231 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- ALG3 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890563; called by muse, mutect2, varscan2
- GAL3ST3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750201995, COSV100360662; called by muse, mutect2, varscan2
- GCNA | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.542); catalogued as rs201497331, COSV101032312; called by muse, mutect2, varscan2
- GDAP1L1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779259030, COSV61156153; called by muse, mutect2, varscan2
- IGHG4 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs764389650; called by muse, mutect2, varscan2
- KCNS3 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1291156923, COSV58406951; called by muse, mutect2, varscan2
- MAP3K19 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100207811; called by muse, mutect2, varscan2
- NAPSA | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53799386; called by muse, mutect2, varscan2
- NCOA3 | c.1070C>G p.T357R | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100506939; called by muse, mutect2
- OR2T2 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs750711705, COSV100737508; called by mutect2, varscan2
- PLXNB3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782047906, COSV100736988; called by muse, mutect2, varscan2
- PTPRG | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV99872150; called by muse, mutect2, varscan2
- RASGEF1C | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1299584370, COSV100745383; called by muse, mutect2, varscan2
- RFX1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs377552211; called by muse, mutect2, varscan2
- RNF113B | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99940245; called by muse, mutect2, varscan2
- SLC6A4 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs190758123, COSV55565955; called by muse, mutect2, varscan2
- TSHZ3 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs550088288, COSV99550232; called by muse, mutect2, varscan2
- XRCC2 | c.789C>G p.N263K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100831556; called by muse, mutect2, varscan2
- ZSCAN10 | c.1543C>T p.R515W (on ENST00000252463; = p.R570W on NM_032805.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1284534513, COSV99373726; called by muse, mutect2, varscan2
- APOB | c.8594del p.N2865Ifs*9 | Frame Shift Del (DEL) | VAF 68/179 reads (38%) | called by mutect2, varscan2
- KMT2C | c.11086del p.Q3696Nfs*9 | Frame Shift Del (DEL) | VAF 96/352 reads (27%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SLC25A10 | c.119del p.V40Gfs*5 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- CDON | c.861C>T p.N287= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV99700298; called by muse, mutect2, varscan2
- IBSP | c.147C>T p.A49= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99883298; called by muse, mutect2, varscan2
- LHX1 | c.1044G>A p.A348= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- MPPED1 | c.108G>A p.R36= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs1044734671, COSV100501095; called by muse, mutect2, varscan2
- NAA11 | c.327G>T p.L109= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99727063; called by muse, mutect2, varscan2
- NCOA3 | c.1068A>T p.V356= | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as COSV100506938; called by muse, mutect2
- NEK6 | c.129G>A p.A43= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs754993371, COSV57216540; called by muse, mutect2, varscan2
- OBSCN | c.8961C>T p.C2987= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs570299277, COSV99470554; called by muse, mutect2, varscan2
- OR2A5 | c.925A>C p.R309= | Silent (SNP) | VAF 29/50 reads (58%) | catalogued as COSV101278607; called by muse, mutect2, varscan2
- SHCBP1 | c.54G>A p.P18= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100317016; called by muse, mutect2, varscan2
- SLC25A39 | c.24C>T p.G8= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99835041; called by muse, mutect2, varscan2
- SLC6A17 | c.2145C>T p.S715= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs151260028; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSHZ3 | c.1098C>T p.Y366= | Silent (SNP) | VAF 82/244 reads (34%) | catalogued as rs746799556, COSV53668349, COSV99552986; called by muse, mutect2, varscan2
- CUX1 | chr7:101816085 C>T | 5'Flank (SNP) | VAF 75/104 reads (72%) | catalogued as COSV99469836; called by muse, mutect2, varscan2
- TMEM105 | n.572G>A | RNA (SNP) | VAF 15/32 reads (47%) | catalogued as rs201571116, COSV100257974; called by muse, mutect2, varscan2
